Somatic mutation profile of tumor specimen C3N-01946-01 (aliquot CPT0163600006) from CPTAC case C3N-01946, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 64.9 years (23,694 days).
Specimen C3N-01946-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e91704a8-870c-4e46-bf55-884acc8867df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01946-31 (Blood Derived Normal), aliquot CPT0163640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f8aef21-8b94-431d-a5b2-b3f54ad4ae3b

The open-access MAF lists 1,508 somatic variants for this specimen: 1,023 protein-altering or splice-affecting, 299 silent, 186 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 751, Silent 299, Frame Shift Del 169, Intron 86, Nonsense Mutation 45, 3'UTR 34, 5'UTR 27, Frame Shift Ins 27, 5'Flank 18, Splice Region 13, RNA 12, Splice Site 12.

Variants (750 of 1,508; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.6184C>T p.R2062W | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs886063038; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 18/187 reads (10%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TMEM67 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs750950408, CM100381, COSV60041511; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 49/392 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1382100120, CM103531, COSV55591915; called by muse, mutect2, varscan2
- AC013489.1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 22/385 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757902237, COSV51553976; called by muse, mutect2
- AC097636.1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV71309642; called by muse, mutect2, varscan2
- ACBD4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs748352757; called by muse, mutect2
- ACTR1B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs372634354; called by muse, mutect2, varscan2
- ACY3 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV54830228; called by muse, mutect2, varscan2
- ADAMTS5 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1404688513, COSV53176244; called by muse, mutect2, varscan2
- ADARB1 | c.2023C>T p.R675C (on ENST00000360697 / NM_001346687.2; = p.R635C on NM_001112.4) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs764962336, COSV100653856; called by muse, mutect2, varscan2
- ADD2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781930613, COSV52464563; called by muse, mutect2
- ADGRA2 | c.724del p.A242Pfs*72 | Frame Shift Del (DEL) | VAF 20/171 reads (12%) | catalogued as rs1487845410; called by mutect2, pindel
- ADGRA2 | c.3187C>A p.L1063I | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as rs1048315197; called by muse, mutect2
- ADGRB3 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.191); catalogued as COSV65383305; called by muse, mutect2, varscan2
- ADGRF5 | c.3214G>A p.A1072T | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs751080249, COSV99345245; called by muse, mutect2, varscan2
- ADGRG6 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51589412; called by muse, mutect2, varscan2
- ADGRG7 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56295981; called by muse, mutect2, varscan2
- ADGRL3 | c.4691C>T p.T1564I (on ENST00000506720 / NM_001322402.2; = p.T1453I on NM_015236.6) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as rs1286724649, COSV101541113; called by muse, mutect2, varscan2
- AGO1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100940963; called by muse, mutect2
- AHCY | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs867752341, COSV54152605; called by muse, mutect2, varscan2
- AHNAK2 | c.6954C>G p.F2318L | Missense Mutation (SNP) | VAF 82/819 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV60922826; called by muse, mutect2
- AL121899.2 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 55/458 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.425); catalogued as rs146171554, COSV101198371; called by muse, mutect2, varscan2
- ALDH16A1 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs978835076; called by muse, mutect2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALOX15B | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs780999730; called by muse, mutect2, varscan2
- ALPK2 | c.1840del p.T614Pfs*81 | Frame Shift Del (DEL) | VAF 37/342 reads (11%) | catalogued as rs1348904009; called by mutect2, pindel, varscan2
- AMER3 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs141161077; called by muse, mutect2, varscan2
- AMPD2 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 68/544 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs1299486132; called by muse, mutect2, varscan2
- ANO1 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.746); catalogued as rs755874611; called by muse, mutect2, varscan2
- APC | c.7836G>A p.W2612* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV57350001; called by muse, mutect2, varscan2
- APEX1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 121/662 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751223947; called by muse, mutect2, varscan2
- APOA5 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs754861714, COSV99911545; called by muse, mutect2
- ARHGAP45 | c.2911G>A p.G971S | Missense Mutation (SNP) | VAF 39/440 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs972271366; called by muse, mutect2
- ARHGEF40 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100070302; called by muse, mutect2, varscan2
- ARID1B | c.5764G>A p.A1922T | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs772464386; called by muse, mutect2, varscan2
- ARNTL | c.1235C>T p.S412F (on ENST00000403290 / NM_001297719.2; = p.S411F on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100724506; called by muse, mutect2, varscan2
- ARSI | c.119C>G p.S40W | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs373063727; called by muse, mutect2, varscan2
- ASAP1 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as rs374657898; called by muse, mutect2, varscan2
- ASAP1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1334794467, COSV100727266; called by muse, varscan2
- ASB16 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs762340517; called by muse, mutect2, varscan2
- ATAD2 | c.4030dup p.S1344Kfs*28 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs775812316; called by mutect2, varscan2
- ATP11A | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 51/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs769415905; called by muse, mutect2, varscan2
- ATP13A4 | c.2563-2A>C p.X855_splice | Splice Site (SNP) | VAF 18/450 reads (4%) | catalogued as COSV61316004; called by muse, mutect2
- B4GALNT2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); catalogued as rs755456102; called by muse, mutect2, varscan2
- BAG3 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755456690; called by muse, mutect2, varscan2
- BAZ2B | c.4621A>G p.S1541G | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs760888026; called by muse, mutect2
- BBS7 | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104385744; called by muse, mutect2
- BCL9L | c.3588del p.P1198Lfs*5 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | catalogued as rs1555172907; called by mutect2, pindel
- BICC1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV65862558; called by muse, mutect2, varscan2
- BOP1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as rs1169347452; called by muse, mutect2, varscan2
- BRD8 | c.3559C>A p.H1187N | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54521998, COSV54522719; called by muse, mutect2, varscan2
- BRPF3 | c.3253C>T p.R1085* | Nonsense Mutation (SNP) | VAF 32/292 reads (11%) | catalogued as rs1414662089, COSV100325865; called by muse, mutect2, varscan2
- BTLA | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.669); catalogued as rs1375423809; called by muse, mutect2
- C19orf18 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV58707884; called by muse, mutect2
- C6orf132 | c.1344del p.S449Afs*68 | Frame Shift Del (DEL) | VAF 27/238 reads (11%) | catalogued as rs774701362; called by mutect2, pindel, varscan2
- C9orf116 | c.283C>T p.R95W (on ENST00000429260 / NM_001048265.2; = p.S79= on NM_144654.3) | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs780042500, COSV65646585; called by muse, mutect2, varscan2
- CACNA1F | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV59903184; called by muse, mutect2, varscan2
- CACNG2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs1021135800; called by muse, mutect2
- CALCOCO1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 28/276 reads (10%) | catalogued as COSV100017230; called by muse, mutect2, varscan2
- CAPN12 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs144919021, COSV53148973; called by muse, mutect2
- CARD11 | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV62754226; called by muse, mutect2
- CAT | c.612del p.I205Ffs*8 | Frame Shift Del (DEL) | VAF 16/165 reads (10%) | catalogued as rs779036767; called by mutect2, pindel, varscan2
- CATSPERB | c.2746A>G p.T916A | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV56426933; called by muse, mutect2, varscan2
- CBFA2T2 | c.1321del p.T441Qfs*5 | Frame Shift Del (DEL) | VAF 17/137 reads (12%) | catalogued as COSV100656585; called by mutect2, pindel, varscan2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 35/333 reads (11%) | catalogued as rs751021664; called by mutect2, pindel, varscan2
- CCDC89 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1162601895, COSV57035107; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 16/141 reads (11%) | catalogued as rs773752200; called by mutect2, pindel, varscan2
- CD248 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1327400821; called by muse, mutect2, varscan2
- CD48 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 33/330 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.132); catalogued as COSV63567207; called by muse, mutect2, varscan2
- CDCA7L | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100651129; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 46/372 reads (12%) | catalogued as rs752398646; called by mutect2, varscan2
- CENPB | c.1312del p.E438Kfs*43 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as rs748211874; called by pindel, varscan2
- CENPF | c.7220G>A p.R2407Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs764028137; called by muse, mutect2, varscan2
- CEP170 | c.1765A>G p.S589G | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1429140041, COSV60511185; called by muse, mutect2, varscan2
- CES2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 66/390 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs761698722, COSV57697447; called by muse, mutect2, varscan2
- CHD6 | c.6865G>A p.G2289R | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64691031; called by muse, mutect2, varscan2
- CHD9 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs770282306, COSV54609079; called by muse, mutect2, varscan2
- CITED2 | c.251del p.P84Rfs*63 | Frame Shift Del (DEL) | VAF 38/298 reads (13%) | catalogued as rs748689446; called by mutect2, varscan2
- CKAP5 | c.2412G>C p.Q804H | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56370624; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 29/228 reads (13%) | catalogued as rs751921758; called by mutect2, varscan2
- CNNM4 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs1295801213, COSV65661789; called by muse, mutect2
- CNOT3 | c.732del p.S245Afs*90 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs753475896; called by mutect2, varscan2
- CNTNAP2 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1277235702; called by muse, mutect2
- COL11A2 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 47/357 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as rs534335166, COSV59494176; called by muse, mutect2, varscan2
- COL9A1 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.081); catalogued as rs1265422552; called by muse, mutect2
- CPAMD8 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.011); catalogued as rs1038581379; called by muse, mutect2, varscan2
- CR1L | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.902); catalogued as COSV54323257; called by muse, mutect2, varscan2
- CSMD3 | c.10651C>T p.R3551C (on ENST00000297405 / NM_001363185.1; = p.R3382C on NM_052900.3) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747094531, COSV52118225, COSV99830646, COSV99853569; called by muse, mutect2, varscan2
- CUX2 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs774127876, COSV55632658; called by muse, varscan2
- CYFIP1 | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs1403318284, COSV100487837; called by muse, mutect2
- CYFIP2 | c.1817G>A p.S606N (on ENST00000616178 / NM_001291722.2; = p.S581N on NM_014376.4) | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV59027731; called by muse, mutect2, varscan2
- CYP26C1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs761068228, COSV99591634; called by muse, mutect2, varscan2
- CYP27C1 | c.798C>T p.G266= | Splice Region (SNP) | VAF 18/196 reads (9%) | catalogued as rs1390517978; called by muse, mutect2
- CYSRT1 | c.494A>C p.H165P (on ENST00000409414; = p.H125P on NM_199001.5) | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs753794275, COSV62986127; called by muse, mutect2, varscan2
- D2HGDH | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 33/403 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs757574221; called by muse, mutect2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 52/258 reads (20%) | catalogued as rs751187768; called by mutect2, varscan2
- DAPK3 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 50/488 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.015); catalogued as rs1476280022; called by muse, mutect2, varscan2
- DENND3 | c.2654C>T p.S885L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753675192; called by muse, mutect2, varscan2
- DHRS7B | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 46/411 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); catalogued as COSV100684104; called by muse, mutect2, varscan2
- DIAPH3 | c.832G>C p.D278H (on ENST00000400324 / NM_001042517.2; = p.D15H on NM_030932.3) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756422711; called by muse, mutect2, varscan2
- DISC1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs760289681; called by muse, mutect2, varscan2
- DLK1 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1445906377; called by muse, mutect2
- DLK1 | c.867G>C p.M289I | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100375079; called by muse, mutect2
- DMRT2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs762245772; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH14 | c.923G>A p.R308Q (on ENST00000445597; = p.R181Q on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs201807754, COSV64780602; called by mutect2, varscan2
- DNAH5 | c.5131C>T p.R1711* | Nonsense Mutation (SNP) | VAF 18/266 reads (7%) | catalogued as rs760869074, COSV54240972; called by muse, mutect2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.5096G>A p.G1699E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs895136259, COSV59476130; called by muse, mutect2
- DNAJA4 | c.1149_1151del p.E383del (on ENST00000343789; = p.E412del on NM_018602.3) | In Frame Del (DEL) | VAF 36/248 reads (15%) | catalogued as rs760646157; called by pindel, varscan2
- DNPEP | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1205145716; called by muse, mutect2
- DOCK1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV54751320; called by muse, mutect2
- DSCAML1 | c.6224G>A p.G2075D (on ENST00000321322; = p.G2015D on NM_020693.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.208); catalogued as rs916593525; called by muse, mutect2, varscan2
- DSP | c.8281G>A p.A2761T | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376751288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.19635G>T p.E6545D (on ENST00000361203 / NM_001374722.1; = p.E4242D on NM_015548.5) | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV55027684; called by muse, mutect2, varscan2
- DUOX1 | c.4568del p.P1523Lfs*3 | Frame Shift Del (DEL) | VAF 35/284 reads (12%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- DUS3L | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs559204251; called by muse, mutect2, varscan2
- DYNC1H1 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 119/591 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV64141494; called by muse, mutect2, varscan2
- DYSF | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 61/453 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.549); catalogued as rs751980650; called by muse, mutect2, varscan2
- EARS2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 49/508 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs865947359; called by muse, mutect2
- EDF1 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1489477651; called by muse, mutect2
- EDN2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs926556784, COSV65423371; called by muse, mutect2, varscan2
- EFHD1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762824561; called by muse, mutect2, varscan2
- EHBP1 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50416030, COSV50442163; called by muse, mutect2
- EHMT2 | c.2483C>T p.T828M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs768152055; called by muse, mutect2, varscan2
- EIF2S3B | c.1190del p.K397Sfs*10 | Frame Shift Del (DEL) | VAF 45/311 reads (14%) | catalogued as rs751695598; called by mutect2, pindel, varscan2
- EIF3H | c.469del p.T157Lfs*8 | Frame Shift Del (DEL) | VAF 22/220 reads (10%) | catalogued as rs753929607; called by mutect2, pindel, varscan2
- ELFN1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs755536565, COSV101300319; called by muse, mutect2, varscan2
- ENO3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 55/555 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); catalogued as COSV56697912; called by muse, mutect2
- EPB41L5 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770943181, COSV55353134; called by muse, mutect2, varscan2
- EPHB2 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757529004, COSV65862198; called by muse, mutect2, varscan2
- EYA3 | c.1255T>C p.Y419H | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1292107854; called by muse, mutect2, varscan2
- F5 | c.692T>A p.M231K | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as CM116350; called by muse, mutect2, varscan2
- FAM124A | c.725G>C p.R242P (on ENST00000322475 / NM_001242312.2; = p.R278P on NM_145019.4) | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54478527, COSV99696507; called by muse, mutect2, varscan2
- FAM171B | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs947600771; called by muse, mutect2
- FAM189A1 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763796689, COSV54277333; called by muse, mutect2, varscan2
- FAM47B | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1257154353; called by muse, mutect2, varscan2
- FAP | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs145562225, COSV51859240; called by muse, mutect2
- FASN | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs774371652; ClinVar: uncertain significance; called by muse, mutect2
- FASTK | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as rs1187704166, COSV52539796; called by muse, mutect2, varscan2
- FAT2 | c.10383del p.Y3462Tfs*16 | Frame Shift Del (DEL) | VAF 57/441 reads (13%) | catalogued as rs747011618; called by mutect2, varscan2
- FBXL12 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs773277520; called by muse, mutect2, varscan2
- FBXO2 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.213); catalogued as rs1209434284; called by muse, mutect2, varscan2
- FBXW12 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as rs201448095, COSV99601682; called by muse, mutect2, varscan2
- FCN2 | c.230del p.P77Lfs*23 | Frame Shift Del (DEL) | VAF 50/419 reads (12%) | catalogued as rs1339990522; called by pindel, varscan2
- FCSK | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs767472330, COSV99850546; called by muse, mutect2
- FER1L5 | c.5017A>C p.K1673Q (on ENST00000623019; = p.K1646Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs763150869; called by muse, mutect2, varscan2
- FGD6 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201103965; called by muse, mutect2
- FGF3 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs782226740, COSV61925288; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 20/139 reads (14%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFBP2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as rs1313756368; called by muse, mutect2, varscan2
- FMNL3 | c.841G>T p.G281* | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | catalogued as COSV53301451; called by muse, mutect2, varscan2
- FMO5 | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV54203968; called by muse, mutect2
- FOXM1 | c.338del p.G113Efs*24 | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | catalogued as rs1565479243, COSV100700782; called by mutect2, pindel, varscan2
- FOXRED2 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV53401943; called by muse, mutect2, varscan2
- FRMPD4 | c.1456G>A p.V486M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs757368234, COSV101044343; called by muse, mutect2, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | catalogued as rs777471402; called by mutect2, varscan2
- GALNT7 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV53929454; called by muse, mutect2
- GALR1 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 52/601 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs763170392, COSV100232079; called by muse, mutect2
- GANAB | c.2830C>T p.R944* | Nonsense Mutation (SNP) | VAF 25/217 reads (12%) | catalogued as rs781470089; called by muse, mutect2, varscan2
- GANC | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 28/136 reads (21%) | catalogued as rs146338244; called by muse, mutect2, varscan2
- GAS2L2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs782524428; called by muse, mutect2
- GBP1 | c.1728A>G p.I576M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV65083885; called by muse, mutect2, varscan2
- GBP6 | c.1760del p.N587Mfs*18 | Frame Shift Del (DEL) | VAF 23/157 reads (15%) | catalogued as rs1557544730; called by mutect2, pindel, varscan2
- GDPD4 | c.442del p.R148Dfs*7 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs757321216; called by mutect2, pindel, varscan2
- GK2 | c.388del p.I130Ffs*23 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | catalogued as rs771628988; called by mutect2, pindel, varscan2
- GNPTG | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 95/831 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772723751; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs370114090; called by mutect2, varscan2
- GPD1 | c.39C>T p.N13= | Splice Region (SNP) | VAF 30/202 reads (15%) | catalogued as rs922947825; called by muse, mutect2, varscan2
- GPN3 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs765647036; called by muse, varscan2
- GRIN2A | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771688818, COSV58023816; called by muse, mutect2, varscan2
- GRIN2B | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 48/511 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV74205994; called by muse, mutect2
- HCAR3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.019); catalogued as rs371201756; called by muse, mutect2, varscan2
- HCN1 | c.134del p.G45Afs*103 | Frame Shift Del (DEL) | VAF 13/127 reads (10%) | catalogued as rs1561248623; called by mutect2, varscan2
- HEATR9 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 41/458 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs750491568; called by muse, mutect2
- HIC1 | c.755C>A p.S252Y (on ENST00000322941 / NM_001098202.1; = p.S233Y on NM_006497.4) | Missense Mutation (SNP) | VAF 52/410 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV53973463; called by muse, mutect2, varscan2
- HIC2 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV68042796; called by muse, mutect2, varscan2
- HIP1R | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 26/157 reads (17%) | catalogued as rs1175735348; called by muse, mutect2, varscan2
- HMCN1 | c.10412G>C p.R3471T | Missense Mutation (SNP) | VAF 53/489 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV54885550; called by muse, mutect2, varscan2
- HORMAD1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59272184; called by muse, mutect2, varscan2
- HOXB5 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1251388030, COSV99494716; called by muse, mutect2, varscan2
- ID1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs758048335, COSV101076770; called by muse, mutect2, varscan2
- IGSF9B | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs770027773, COSV100318465; called by muse, mutect2, varscan2
- IKBKB | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV100645878; called by muse, mutect2, varscan2
- IL18 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1266223590; called by muse, mutect2, varscan2
- INTS1 | c.5117G>A p.R1706H | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs200824460; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs1561359523; called by mutect2, varscan2
- ITGA7 | c.3041C>T p.A1014V (on ENST00000555728; = p.A970V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs201354330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAKMIP3 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 16/219 reads (7%) | catalogued as rs369595261; called by muse, mutect2
- JAM3 | c.523C>A p.R175S | Missense Mutation (SNP) | VAF 30/786 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV100138226; called by muse, mutect2
- KAT6A | c.3758C>G p.S1253C | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55909510; called by muse, mutect2, varscan2
- KCNG4 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs754870292; called by muse, mutect2, varscan2
- KCNH6 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs746553730; called by muse, mutect2
- KCNJ16 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as rs1445738439; called by muse, mutect2, varscan2
- KCNJ5 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs746240972, COSV57964945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM2B | c.3016del p.R1006Gfs*37 | Frame Shift Del (DEL) | VAF 26/198 reads (13%) | catalogued as rs1555288650, COSV65639291; called by pindel, varscan2
- KDM5B | c.2152C>T p.H718Y | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767368433; called by muse, mutect2, varscan2
- KDR | c.1835T>C p.L612S | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV55777037; called by muse, mutect2
- KIAA0408 | c.2045A>G p.N682S | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV64115734; called by muse, mutect2, varscan2
- KIF26B | c.5680G>A p.G1894S | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356964165, COSV100831777; called by muse, mutect2
- KIRREL1 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255668159; called by muse, mutect2, varscan2
- KMT2C | c.5327T>C p.V1776A | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV51509234; called by muse, mutect2, varscan2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 36/241 reads (15%) | catalogued as rs960845807, COSV54929560; called by mutect2, varscan2
- KRT3 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as rs866052686; called by muse, mutect2, varscan2
- LAMB1 | c.1216C>G p.Q406E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99740378; called by muse, mutect2, varscan2
- LAMC3 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 144/843 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs375139277; called by muse, mutect2, varscan2
- LARP1B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs1343171236; called by muse, mutect2
- LDB2 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58765159; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- LEFTY1 | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 54/462 reads (12%) | catalogued as COSV55282516, COSV55282913; called by muse, mutect2, varscan2
- LGALS3BP | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs776549166, COSV53164511, COSV53164591; called by muse, mutect2, varscan2
- LGALS9B | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs758795245; called by muse, mutect2, varscan2
- LPIN3 | c.1409del p.N470Tfs*10 | Frame Shift Del (DEL) | VAF 25/283 reads (9%) | catalogued as rs1412227875; called by mutect2, pindel
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 34/238 reads (14%) | catalogued as rs139915490; called by mutect2, varscan2
- LRP2 | c.12545C>T p.T4182I | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV55549623; called by muse, mutect2, varscan2
- LRP2 | c.11541C>G p.F3847L | Missense Mutation (SNP) | VAF 56/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55550013; called by muse, varscan2
- LRP5 | c.4733C>T p.T1578M | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974175023; called by muse, mutect2
- LRP6 | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1265718831, COSV53787276; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LTBP3 | c.805del p.R269Gfs*119 | Frame Shift Del (DEL) | VAF 41/406 reads (10%) | catalogued as COSV57239256; called by mutect2, pindel, varscan2
- LYST | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV101089135; called by muse, mutect2, varscan2
- MAGEB4 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs772790238, COSV66775163, COSV66776098; called by muse, mutect2, varscan2
- MAMSTR | c.1013T>G p.L338R (on ENST00000318083 / NM_001130915.2; = p.L235R on NM_182574.2) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780394599; called by muse, mutect2, varscan2
- MAP3K15 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs1219857102; called by muse, mutect2, varscan2
- MAP3K21 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486052733, COSV64044637; called by muse, mutect2, varscan2
- MAPK12 | c.427-5dup | Splice Region (INS) | VAF 16/139 reads (12%) | catalogued as rs752922316; called by mutect2, pindel, varscan2
- MASP1 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV51461845; called by muse, mutect2
- MASTL | c.2188del p.V730Wfs*10 (on ENST00000375940 / NM_001372029.1; = p.V729Wfs*10 on NM_032844.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/384 reads (10%) | catalogued as COSV104416816; called by mutect2, pindel
- MATN1 | c.85del p.Q29Sfs*32 | Frame Shift Del (DEL) | VAF 12/121 reads (10%) | catalogued as rs1419789464; called by mutect2, pindel, varscan2
- ME1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs1330237037, COSV63838094; called by muse, mutect2
- MEFV | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs104895085, CM014209; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MEGF6 | c.3155G>T p.G1052V | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs766603927; called by muse, mutect2
- MEX3D | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1472827106, COSV101183566; called by muse, mutect2, varscan2
- MIB2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 30/216 reads (14%) | catalogued as COSV61755666; called by muse, mutect2, varscan2
- MICU2 | c.1303del p.*435Nfs*21 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV66675453; called by mutect2, pindel, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MINK1 | c.2527G>A p.G843R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs368947159; called by muse, mutect2, varscan2
- MISP | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779020440, COSV53120008; called by muse, mutect2, varscan2
- MON1B | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs374071418; called by muse, mutect2, varscan2
- MPPED1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs749308599, COSV68837855, COSV68838445; called by muse, mutect2, varscan2
- MPST | c.278C>T p.A93V (on ENST00000341116 / NM_001369904.2; = p.A113V on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs769020678; called by muse, mutect2, varscan2
- MS4A2 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV54013125; called by muse, mutect2
- MSI1 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs769508876, COSV99981695; called by muse, mutect2
- MUC16 | c.40261G>T p.G13421C | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66693723, COSV66694086; called by muse, mutect2, varscan2
- MUC16 | c.37784G>A p.G12595D | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1180669576; called by muse, mutect2
- MVP | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs752641335; called by muse, mutect2, varscan2
- MYOD1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.111); catalogued as rs745397864; called by muse, mutect2, varscan2
- NACC1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1421117990; called by muse, mutect2
- NAT8 | c.147dup p.P50Afs*47 | Frame Shift Ins (INS) | VAF 12/105 reads (11%) | catalogued as rs745756582; called by mutect2, pindel, varscan2
- NBEAL2 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1191007923; called by muse, mutect2
- NIPBL | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs755570564; called by muse, mutect2
- NIPBL | c.7207C>T p.R2403C | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99238549; called by muse, mutect2, varscan2
- NKD1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.573); catalogued as rs369647847; called by muse, mutect2
- NKX1-2 | c.428del p.P143Rfs*52 | Frame Shift Del (DEL) | VAF 15/135 reads (11%) | catalogued as rs918341173; called by mutect2, pindel, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRC5 | c.834del p.F278Lfs*5 | Frame Shift Del (DEL) | VAF 29/241 reads (12%) | catalogued as rs1567551082, COSV52664719; called by mutect2, pindel, varscan2
- NLRX1 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as rs1043304177, COSV52707378; called by muse, mutect2
- NOS3 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs377756718; called by muse, mutect2
- NOTCH1 | c.4301del p.G1434Vfs*11 | Frame Shift Del (DEL) | VAF 21/128 reads (16%) | catalogued as COSV53029905; called by mutect2, pindel, varscan2
- NOTCH1 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs752071569, COSV53039096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPHP3 | c.3032C>T p.A1011V | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202145723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPHS2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs201355305, COSV62634950; ClinVar: uncertain significance; called by muse, mutect2
- NPR1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs994822671, COSV64141077; called by muse, mutect2, varscan2
- NR4A2 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 42/398 reads (11%) | catalogued as COSV59894010; called by muse, varscan2
- NRXN2 | c.3991G>A p.V1331M | Missense Mutation (SNP) | VAF 69/563 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV99633437; called by muse, mutect2, varscan2
- NTF3 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58417235; called by muse, mutect2, varscan2
- NUDCD1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs867850829, COSV53454423; called by muse, mutect2, varscan2
- OR10H5 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs372682146; called by muse, mutect2, varscan2
- OR51Q1 | c.96del p.V33Sfs*38 | Frame Shift Del (DEL) | VAF 27/246 reads (11%) | catalogued as COSV100332949; called by mutect2, pindel, varscan2
- OR5F1 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV53547677; called by muse, mutect2, varscan2
- PANX2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1485043074, COSV50293248, COSV50308756; called by muse, mutect2, varscan2
- PCCA | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs921743087; called by muse, mutect2
- PCDH8 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs1384362130; called by muse, mutect2, varscan2
- PCDHGA2 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53895716; called by muse, mutect2, varscan2
- PCDHGB3 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54061851; called by muse, mutect2, varscan2
- PDLIM1 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV61474964; called by muse, mutect2, varscan2
- PELI1 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62730337; called by muse, mutect2
- PEX7 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs746546028; called by muse, varscan2
- PHRF1 | c.2476C>T p.R826W (on ENST00000264555 / NM_001286581.2; = p.R825W on NM_020901.4) | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs931614753, COSV52761574; called by muse, mutect2, varscan2
- PI4KA | c.5922C>T p.I1974= | Splice Region (SNP) | VAF 20/55 reads (36%) | catalogued as rs200341922; called by muse, varscan2
- PI4KA | c.2284A>G p.S762G | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs1392530296; called by muse, mutect2, varscan2
- PIK3C2A | c.4853C>T p.T1618M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767495516, COSV56402611; called by muse, mutect2, varscan2
- PITPNM1 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs757915989; called by muse, mutect2
- PLCB2 | c.1733A>C p.E578A | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53037908; called by muse, mutect2, varscan2
- PLCG2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 53/533 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs750403828, COSV63877238; called by muse, mutect2, varscan2
- PLCXD1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.092); catalogued as rs746029168; called by muse, mutect2
- PLEC | c.6695A>C p.E2232A (on ENST00000322810 / NM_201380.4; = p.E2122A on NM_000445.5) | Missense Mutation (SNP) | VAF 85/786 reads (11%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs923805947; called by muse, mutect2, varscan2
- PLEC | c.3542C>T p.S1181F (on ENST00000322810 / NM_201380.4; = p.S1071F on NM_000445.5) | Missense Mutation (SNP) | VAF 106/497 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100517807; called by muse, varscan2
- PLEKHM1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779056350; called by muse, mutect2
- PLXNB2 | c.4034G>C p.R1345P | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63780926; called by muse, varscan2
- PLXNB2 | c.3858C>A p.F1286L | Missense Mutation (SNP) | VAF 85/635 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63780337; called by muse, mutect2, varscan2
- PLXNB2 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs201521733, COSV63784231; called by muse, mutect2, varscan2
- POLR3B | c.1990C>G p.L664V | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV57286155; called by muse, mutect2, varscan2
- POU3F2 | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60409468; called by muse, mutect2, varscan2
- PPFIA4 | c.1798C>T p.R600C (on ENST00000447715; = p.R601C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs916750313; called by muse, mutect2, varscan2
- PPP1R12B | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs143792888; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PPP4C | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs756694260; called by muse, mutect2, varscan2
- PPP4R4 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as rs1295955130, COSV58553355; called by muse, mutect2, varscan2
- PRELID1 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs770853591; called by muse, mutect2, varscan2
- PRKAB2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as rs782092808; called by muse, mutect2, varscan2
- PROX2 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV71520212; called by muse, mutect2, varscan2
- PRR23A | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs1302210826, COSV67213326; called by muse, varscan2
- PRR23C | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1277613821; called by muse, mutect2, varscan2
- PSG3 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as COSV59506313; called by muse, mutect2, varscan2
- PSME4 | c.4130G>A p.R1377Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174983859; called by muse, mutect2
- PSME4 | c.3523C>A p.L1175M | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV66364375; called by muse, mutect2
- PTGER3 | c.568del p.L190Cfs*53 | Frame Shift Del (DEL) | VAF 19/192 reads (10%) | catalogued as COSV60695475; called by mutect2, pindel, varscan2
- PTK7 | c.2472G>C p.E824D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs762464563; called by muse, mutect2, varscan2
- PTPRB | c.4346del p.P1449Lfs*9 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | catalogued as rs1476690081; called by mutect2, pindel
- PTPRG | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.333); catalogued as rs762084994, COSV55631303; called by muse, mutect2
- PTPRS | c.1239del p.S414Afs*30 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | catalogued as rs1390768500; called by mutect2, pindel, varscan2
- PTPRU | c.377del p.G126Afs*10 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | catalogued as COSV60536507; called by mutect2, pindel
- RAC1 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV61821585, COSV61824963; called by mutect2, varscan2
- RAE1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758243618, COSV64799081; called by muse, mutect2, varscan2
- RAET1G | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372232574; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 35/303 reads (12%) | catalogued as rs1251406873; called by mutect2, varscan2
- RAI1 | c.1493C>A p.S498* | Nonsense Mutation (SNP) | VAF 41/241 reads (17%) | catalogued as COSV99883405; called by muse, mutect2, varscan2
- RALGDS | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.389); catalogued as rs1176906450; called by muse, mutect2, varscan2
- RAPH1 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs776674212; called by muse, mutect2, varscan2
- RASSF10 | c.905A>C p.E302A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs948072323; called by muse, mutect2, varscan2
- RAVER2 | c.2060del p.K687Rfs*15 (on ENST00000294428 / NM_001366165.1; = p.K674Rfs*15 on NM_018211.4) | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | catalogued as COSV53805154; called by mutect2, pindel
- RBM7 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs142687993; called by muse, mutect2
- RBM8A | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57162981; called by muse, mutect2, varscan2
- RC3H2 | c.1433C>G p.S478C | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV61802344; called by muse, mutect2
- RESF1 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs375678424; called by muse, mutect2, varscan2
- RGPD4 | c.3012C>A p.F1004L | Missense Mutation (SNP) | VAF 42/565 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61745897; called by muse, mutect2
- RIMS1 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99326844; called by muse, mutect2, varscan2
- RNF5 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as rs906659409; called by muse, mutect2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1436309196; called by mutect2, varscan2
- ROBO4 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); catalogued as rs766292800; called by muse, mutect2, varscan2
- RPL7L1 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.963); catalogued as rs1291342711; called by muse, mutect2, varscan2
- RRBP1 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs763155990, COSV55699838; called by muse, mutect2, varscan2
- RSF1 | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57837503; called by muse, mutect2, varscan2
- RWDD3 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs755496684; called by muse, mutect2, varscan2
- SARM1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs372349604; called by muse, mutect2
- SART1 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1469285112, COSV56713386; called by muse, mutect2
- SBF1 | c.5600G>A p.R1867H | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1241548260, COSV53295362; called by muse, mutect2, varscan2
- SCAP | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760837280, COSV55563348; called by muse, mutect2, varscan2
- SCART1 | c.1923del p.R642Gfs*20 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs1285387406; called by mutect2, pindel, varscan2
- SCN2A | c.1143G>C p.M381I | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51858287; called by muse, mutect2, varscan2
- SCO2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.683); catalogued as rs962372149; called by muse, mutect2, varscan2
- SDS | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as rs747689476, COSV57454444; called by muse, mutect2
- SEC14L3 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867141692; called by muse, mutect2
- SEC61A2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs1007259908; called by muse, mutect2, varscan2
- SEMA4D | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs980317976, COSV59394120; called by muse, mutect2
- SEPTIN12 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs768378976, COSV51618362; called by muse, mutect2, varscan2
- SERINC3 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV54857224, COSV99668020; called by muse, mutect2
- SERPINB13 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as rs200737594, COSV99501207; called by muse, mutect2
- SERPINB4 | c.223-1G>T p.X75_splice | Splice Site (SNP) | VAF 17/135 reads (13%) | catalogued as rs754805923, COSV100346024; called by muse, mutect2, varscan2
- SETDB1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV54979770, COSV54984186; called by muse, mutect2
- SFRP1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.673); catalogued as rs752829505; called by muse, varscan2
- SH3BP2 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as rs151048521; called by muse, mutect2, varscan2
- SHB | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs7872846; called by muse, mutect2, varscan2
- SHH | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 52/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM126231, COSV99793579; called by muse, mutect2, varscan2
- SLC11A1 | c.597del p.F199Lfs*5 | Frame Shift Del (DEL) | VAF 29/223 reads (13%) | catalogued as rs1362974823; called by mutect2, varscan2
- SLC22A1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778547168, COSV61452150; called by muse, mutect2
- SLC34A3 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1357255349, COSV100746618; called by muse, mutect2, varscan2
- SLC5A10 | c.389del p.G130Afs*63 | Frame Shift Del (DEL) | VAF 17/198 reads (9%) | catalogued as COSV100525283; called by mutect2, pindel
- SLC7A8 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377518623; called by muse, mutect2
- SLC9A3 | c.2191A>C p.S731R | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs758009579; called by muse, mutect2
- SLIT3 | c.4186G>T p.G1396C | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265092; called by muse, mutect2, varscan2
- SLTM | c.251-5C>T | Splice Region (SNP) | VAF 25/130 reads (19%) | catalogued as rs138442887; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs766085867, COSV100391091; called by mutect2, varscan2
- SMARCA2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs774084308; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1257129093; called by mutect2, pindel
- SMG9 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 36/390 reads (9%) | catalogued as rs754073488; called by muse, mutect2
- SMPD4 | c.1234G>A p.V412I (on ENST00000409031 / NM_017951.4; = p.V383I on NM_017751.4) | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as rs200309069; called by muse, mutect2, varscan2
- SMYD5 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242865; called by muse, mutect2, varscan2
- SNED1 | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs774944493, COSV100122074; called by muse, mutect2, varscan2
- SNX1 | c.38G>T p.R13I | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV99975827; called by muse, mutect2
- SOGA3 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100846888; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPAG16 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs757379367; called by muse, mutect2, varscan2
- SPAG17 | c.6459G>T p.K2153N | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.31); catalogued as COSV104413285, COSV60470740; called by muse, mutect2, varscan2
- SPATA3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 54/534 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372370905; called by muse, mutect2
- SPIDR | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52388120; called by muse, mutect2, varscan2
- SPON1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs782744891; called by muse, mutect2, varscan2
- SPRED2 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100710308; called by muse, mutect2, varscan2
- SPTBN5 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 137/721 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs1404978230, COSV58020007; called by muse, mutect2, varscan2
- SRRM2 | c.3455C>A p.S1152Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV57073015; called by muse, mutect2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | catalogued as rs761897392; called by mutect2, pindel, varscan2
- STEAP1 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV51881522; called by muse, mutect2, varscan2
- STK10 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs370433044; called by muse, mutect2, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 34/345 reads (10%) | catalogued as rs1553764068; called by mutect2, pindel
- SVEP1 | c.9218C>T p.A3073V | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as rs912108341, COSV52838268; called by muse, mutect2, varscan2
- SYNE1 | c.19936del p.T6646Hfs*6 (on ENST00000367255 / NM_182961.4; = p.T6575Hfs*6 on NM_033071.3) | Frame Shift Del (DEL) | VAF 39/313 reads (12%) | catalogued as COSV99578330; called by mutect2, pindel, varscan2
- SYT4 | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54902741; called by muse, mutect2, varscan2
- TAS1R2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as rs763431159; called by muse, mutect2, varscan2
- TCF15 | c.548del p.G183Afs*4 | Frame Shift Del (DEL) | VAF 24/205 reads (12%) | catalogued as rs998181354; called by mutect2, pindel, varscan2
- TDRD9 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as rs1177967089, COSV59156768; called by muse, mutect2, varscan2
- TESPA1 | c.890G>A p.R297Q (on ENST00000316577 / NM_001098815.3; = p.R159Q on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs371019313, COSV57258461; called by muse, mutect2
- TIGD6 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs763611365, COSV99697840; called by muse, mutect2
- TLCD1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 35/289 reads (12%) | catalogued as COSV99261906; called by muse, mutect2, varscan2
- TLCD3A | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100021245; called by muse, mutect2, varscan2
- TLN1 | c.5410A>G p.T1804A | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100147459; called by muse, mutect2, varscan2
- TLR10 | c.2256del p.A753Hfs*28 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs564674109; called by mutect2, varscan2
- TLR2 | c.370_373del p.S124Lfs*2 | Frame Shift Del (DEL) | VAF 4/51 reads (8%) | catalogued as rs767943819; called by mutect2, pindel
- TM9SF2 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as rs1290533882, COSV64506397; called by muse, mutect2
- TMC5 | c.2103G>C p.L701F (on ENST00000396229 / NM_001105248.1; = p.L455F on NM_024780.5) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV54904129; called by muse, mutect2
- TMC5 | c.2482del p.R828Gfs*5 (on ENST00000396229 / NM_001105248.1; = p.R582Gfs*5 on NM_024780.5) | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as COSV54903714; called by mutect2, pindel, varscan2
- TMEM126B | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as rs112358510; called by muse, mutect2
- TMEM132A | c.1480del p.L494Cfs*82 (on ENST00000453848 / NM_178031.3; = p.L495Cfs*82 on NM_017870.4) | Frame Shift Del (DEL) | VAF 50/385 reads (13%) | catalogued as COSV50001098; called by mutect2, pindel, varscan2
- TMEM240 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as rs765598128; called by muse, mutect2
- TMEM259 | c.1732del p.H578Tfs*24 | Frame Shift Del (DEL) | VAF 27/261 reads (10%) | catalogued as rs1226986734; called by mutect2, pindel, varscan2
- TRAF3IP3 | c.223_225del p.E75del | In Frame Del (DEL) | VAF 32/305 reads (10%) | catalogued as rs778808662; called by pindel, varscan2
- TRGV9 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1354051261; called by muse, mutect2, varscan2
- TRIM31 | c.1143_1145del p.D381del | In Frame Del (DEL) | VAF 51/502 reads (10%) | catalogued as rs1273239270; called by pindel, varscan2
- TRIM43 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as rs368012209; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TSKU | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs374219122; called by muse, mutect2
- TTC38 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768477456, COSV101123923; called by muse, mutect2, varscan2
- TTF2 | c.3398del p.K1133Rfs*47 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs1557835640; called by mutect2, varscan2
- TTLL13P | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758711693; called by muse, mutect2
- TTLL13P | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as rs1395686021, COSV60037200; called by muse, mutect2, varscan2
- TTN | c.47407C>T p.R15803C (on ENST00000591111; = p.R8379C on NM_003319.4) | Missense Mutation (SNP) | VAF 28/338 reads (8%) | PolyPhen probably damaging (0.917); catalogued as rs778094750, COSV59878854; ClinVar: uncertain significance; called by muse, mutect2
- TTYH3 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1384705562; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs760251146; called by mutect2, varscan2
- UBE4B | c.2323C>T p.R775C (on ENST00000343090 / NM_001105562.3; = p.R646C on NM_006048.5) | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53534906; called by muse, mutect2
- UBN2 | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1004814525; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs754475641; called by muse, mutect2
- UNC13C | c.2126C>G p.S709* | Nonsense Mutation (SNP) | VAF 7/95 reads (7%) | catalogued as COSV52875589; called by muse, mutect2
- UNC79 | c.4298C>T p.A1433V (on ENST00000393151 / NM_001346218.2; = p.A1256V on NM_020818.5) | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1019331151, COSV56407731; called by muse, mutect2, varscan2
- URB1 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63220756; called by muse, mutect2
- USP11 | c.1849del p.L617Sfs*19 (on ENST00000218348; = p.L574Sfs*19 on NM_001371072.1) | Frame Shift Del (DEL) | VAF 43/183 reads (23%) | catalogued as COSV54474231; called by mutect2, pindel, varscan2
- USP20 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs201112284, COSV100204126; called by muse, mutect2, varscan2
- USP32 | c.3983A>C p.Q1328P | Missense Mutation (SNP) | VAF 37/371 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs768544066; called by muse, mutect2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- USP35 | c.3005del p.G1002Afs*25 | Frame Shift Del (DEL) | VAF 13/117 reads (11%) | catalogued as rs748738592; called by mutect2, pindel, varscan2
- USP42 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs758322239, COSV60358241; called by muse, mutect2, varscan2
- VGF | c.1483del p.R495Vfs*179 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | catalogued as rs779099185; called by mutect2, pindel
- VN1R4 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV60804700; called by muse, mutect2
- VPS9D1 | c.1259-1G>C p.X420_splice | Splice Site (SNP) | VAF 11/80 reads (14%) | catalogued as COSV66994836; called by muse, mutect2
- VSTM1 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV58076064; called by muse, mutect2
- VWA5B1 | c.3583C>T p.R1195C (on ENST00000375079; = p.R1190C on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs560960544, COSV57051865; called by muse, mutect2, varscan2
- VWF | c.5686C>T p.P1896S | Missense Mutation (SNP) | VAF 43/417 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1205743847; called by muse, mutect2, varscan2
- WNT7B | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs574645578; called by muse, mutect2, varscan2
- WWC2 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750636404; called by muse, mutect2, varscan2
- ZBED2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 28/363 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.188); catalogued as rs759352888, COSV51914734; called by muse, mutect2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H3 | c.1330C>A p.R444S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52791120; called by muse, mutect2, varscan2
- ZDBF2 | c.5624del p.K1875Rfs*39 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | catalogued as rs770232797, COSV65623567; called by mutect2, varscan2
- ZDHHC11B | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.494); catalogued as rs577836953; called by muse, varscan2
- ZEB2 | c.1426del p.M476Wfs*11 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as CD052131; called by mutect2, pindel, varscan2
- ZFHX4 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 40/415 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs750806468, COSV50894948; called by muse, mutect2, varscan2
- ZFHX4 | c.9038G>T p.G3013V | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50850555; called by muse, mutect2, varscan2
- ZNF160 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs756011876; called by muse, mutect2, varscan2
- ZNF219 | c.2157del p.Q720Kfs*28 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | catalogued as COSV53883789; called by mutect2, pindel, varscan2
- ZNF23 | c.720C>G p.I240M | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV100612113; called by muse, mutect2, varscan2
- ZNF292 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60546480; called by muse, mutect2
- ZNF358 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs928972502; called by muse, mutect2, varscan2
- ZNF460 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1199473628; called by muse, mutect2, varscan2
- ZNF469 | c.10207G>A p.E3403K (on ENST00000437464; = p.E3431K on NM_001367624.2) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV71259036; called by muse, mutect2, varscan2
- ZNF526 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 81/624 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs543011490, COSV55899844; called by muse, mutect2, varscan2
- ZNF541 | c.692dup p.E232Gfs*50 | Frame Shift Ins (INS) | VAF 16/134 reads (12%) | catalogued as rs780386192; called by mutect2, varscan2
- ZNF543 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100386772; called by muse, mutect2, varscan2
- ZNF648 | c.1501del p.E501Rfs*116 | Frame Shift Del (DEL) | VAF 41/333 reads (12%) | catalogued as COSV60572766; called by mutect2, pindel, varscan2
- ZNF69 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769679589; called by muse, mutect2
- ZNF749 | c.1807C>T p.Q603* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs1240270875; called by muse, mutect2, varscan2
- ZNF853 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057462270; called by muse, mutect2, varscan2
- ZNF853 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 64/477 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1457638924, COSV71922823; called by muse, mutect2, varscan2
- ZNF99 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 22/250 reads (9%) | catalogued as COSV68055661; called by muse, mutect2
- ZRANB3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV51498341; called by muse, mutect2
- ZSCAN10 | c.817G>A p.E273K (on ENST00000252463; = p.E328K on NM_032805.3) | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99374144; called by muse, varscan2
- ZSWIM7 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as rs1267671688; called by muse, mutect2, varscan2
- ABCC10 | c.4427A>T p.Q1476L (on ENST00000372530 / NM_001198934.2; = p.Q1448L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- ABHD11 | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by mutect2, varscan2
- ABHD17C | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 48/404 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ABHD4 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ABT1 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ABTB2 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC090517.4 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC127029.3 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 60/642 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ACOT12 | c.1012C>G p.P338A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ACVR1B | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ADAM23 | c.2123T>C p.V708A | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADAMTS14 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2
- ADARB2 | c.989A>C p.Q330P | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADCK5 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ADCY4 | c.1919T>C p.L640P | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRF2 | c.1201G>C p.E401Q (on ENST00000296862 / NM_001368115.2; = p.E333Q on NM_153839.7) | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ADGRV1 | c.17509G>A p.E5837K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2
- ADSS2 | c.1167A>G p.P389= | Splice Region (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- AHNAK | c.14011G>C p.D4671H | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- AHNAK2 | c.7610C>T p.S2537F | Missense Mutation (SNP) | VAF 73/735 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2
- AIRE | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.23); called by muse, mutect2
- AJUBA | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- AMPD2 | c.1286C>A p.T429N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ANGPTL6 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ANK3 | c.3359del p.K1120Sfs*35 (on ENST00000280772 / NM_001320874.2; = p.K254Sfs*35 on NM_001149.3) | Frame Shift Del (DEL) | VAF 21/189 reads (11%) | called by mutect2, varscan2
- ANKRD33B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ANKRD36B | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ANKRD63 | c.945C>G p.H315Q | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- AOC1 | c.568del p.R190Gfs*18 | Frame Shift Del (DEL) | VAF 26/248 reads (10%) | called by mutect2, pindel, varscan2
- ARHGAP1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP21 | c.4606T>C p.S1536P | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP31 | c.1676A>T p.D559V | Missense Mutation (SNP) | VAF 52/339 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ARHGAP33 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- ARHGAP39 | c.1757A>C p.E586A | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGAP42 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARL9 | c.787G>C p.D263H (on ENST00000640821 / NM_001363794.2; = p.D121H on NM_206919.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ARPP21 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASAP1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, varscan2
- ATP1A1 | c.1588dup p.L530Pfs*3 | Frame Shift Ins (INS) | VAF 30/277 reads (11%) | called by mutect2, pindel, varscan2
- ATP8A1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- BAHCC1 | c.1607del p.P536Qfs*15 | Frame Shift Del (DEL) | VAF 20/164 reads (12%) | called by mutect2, varscan2
- BCAS2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- BHLHE23 | c.587C>T p.A196V (on ENST00000370346; = p.A212V on NM_080606.4) | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- BOC | c.2757G>T p.Q919H | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, varscan2
- BPIFB4 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRPF3 | c.1688G>T p.R563L | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRWD3 | c.4698G>T p.E1566D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- BSCL2 | c.573+6T>C | Splice Region (SNP) | VAF 54/475 reads (11%) | called by muse, mutect2, varscan2
- C10orf90 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- C16orf86 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf78 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- C19orf18 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- C1orf167 | c.3175del p.A1059Pfs*110 | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | called by mutect2, pindel, varscan2
- C2CD3 | c.4928G>C p.R1643T | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- C2CD4C | c.961C>A p.R321S | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C2CD5 | c.2249T>G p.L750R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- C2CD5 | c.1053del p.F351Lfs*3 | Frame Shift Del (DEL) | VAF 23/186 reads (12%) | called by mutect2, varscan2
- C4BPA | c.1022A>G p.D341G | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- C5orf58 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- C7orf61 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- CACHD1 | c.1664G>T p.S555I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CACNA1S | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- CACNB4 | c.1449T>G p.D483E | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNG2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CACNG8 | c.55del p.V19Cfs*5 | Frame Shift Del (DEL) | VAF 31/262 reads (12%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.4441G>T p.E1481* | Nonsense Mutation (SNP) | VAF 53/434 reads (12%) | called by muse, mutect2, varscan2
- CARD6 | c.2414T>C p.V805A | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.458); called by muse, mutect2
- CARNMT1 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CASP8AP2 | c.5833G>T p.G1945W | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CATSPER4 | c.685dup p.S229Ffs*41 | Frame Shift Ins (INS) | VAF 42/469 reads (9%) | called by mutect2, pindel
- CCDC14 | c.2401C>T p.P801S (on ENST00000488653; = p.P753S on NM_022757.5) | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- CCDC168 | c.10364G>T p.R3455I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CCDC18 | c.2324del p.N775Ifs*35 (on ENST00000343253 / NM_001306076.1; = p.N776Ifs*35 on NM_206886.4) | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- CCDC78 | c.104dup p.T36Hfs*20 | Frame Shift Ins (INS) | VAF 30/270 reads (11%) | called by mutect2, varscan2
- CCL8 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 30/292 reads (10%) | called by muse, mutect2, varscan2
- CCM2L | c.830del p.G277Efs*32 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- CCN6 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 66/667 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCND1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNL1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CCNT1 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT7 | c.61del p.Q21Sfs*3 | Frame Shift Del (DEL) | VAF 35/256 reads (14%) | called by mutect2, pindel, varscan2
- CD22 | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD74 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD74 | c.21G>C p.R7S | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC5L | c.1646C>G p.S549* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- CDH18 | c.2174T>C p.L725P | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CDH26 | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDH3 | c.2117dup p.G707Wfs*8 | Frame Shift Ins (INS) | VAF 27/263 reads (10%) | called by mutect2, pindel, varscan2
- CELSR2 | c.5873A>T p.D1958V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP295 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2
- CEP85L | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CFAP69 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- CHRM3 | c.407T>C p.L136S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CHST14 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CLHC1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLIP2 | c.821_825del p.P274Lfs*94 | Frame Shift Del (DEL) | VAF 42/330 reads (13%) | called by mutect2, pindel, varscan2
- CLNS1A | c.11T>A p.L4H | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CLPTM1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 49/445 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- COL20A1 | c.1204del p.R402Gfs*7 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- COL3A1 | c.2870dup p.L958Sfs*11 | Frame Shift Ins (INS) | VAF 31/291 reads (11%) | called by mutect2, pindel, varscan2
- COL5A1 | c.4921G>T p.D1641Y | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL8A1 | c.2015del p.G672Afs*14 | Frame Shift Del (DEL) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- CPNE3 | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.604); called by muse, mutect2
- CPNE6 | c.217dup p.R73Pfs*6 | Frame Shift Ins (INS) | VAF 31/242 reads (13%) | called by mutect2, pindel, varscan2
- CPT1C | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CRYGB | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- CSMD1 | c.4687dup p.E1563Gfs*5 (on ENST00000520002; = p.E1562Gfs*5 on NM_033225.6) | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- CSMD3 | c.8681A>C p.N2894T (on ENST00000297405 / NM_001363185.1; = p.N2725T on NM_052900.3) | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CUL7 | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP4F2 | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by mutect2, varscan2
- CYTIP | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- DAAM1 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DAAM2 | c.2281G>T p.A761S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.262); called by muse, mutect2
- DAGLB | c.1125del p.T376Pfs*50 | Frame Shift Del (DEL) | VAF 26/260 reads (10%) | called by mutect2, pindel, varscan2
- DARS1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- DARS2 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCN | c.974C>A p.S325* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- DDX50 | c.1017del p.K339Nfs*3 | Frame Shift Del (DEL) | VAF 11/121 reads (9%) | called by mutect2, pindel
- DEDD2 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DERPC | c.1571dup p.*525Lfs*25 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, pindel
- DGKB | c.31A>C p.S11R | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- DGKI | c.2020T>C p.S674P | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DIRAS2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DISC1 | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 82/569 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DKK2 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- DLG1 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- DLG5 | c.2841G>A p.W947* | Nonsense Mutation (SNP) | VAF 59/499 reads (12%) | called by muse, mutect2, varscan2
- DNAH17 | c.10048del p.V3350Sfs*28 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by pindel, varscan2
- DNAH5 | c.3748C>A p.L1250I | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2
- DNHD1 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- DOCK11 | c.848del p.K283Rfs*4 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- DST | c.5579G>A p.G1860E | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.2531C>A p.P844H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); called by muse, mutect2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/306 reads (13%) | called by mutect2, pindel, varscan2
- EDC4 | c.3775C>A p.L1259I | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EDRF1 | c.1830G>C p.E610D (on ENST00000356792 / NM_001202438.2; = p.E576D on NM_015608.2) | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.413); called by muse, mutect2
- EFHD2 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EHHADH | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- EIF2AK4 | c.961del p.M321Wfs*31 | Frame Shift Del (DEL) | VAF 41/252 reads (16%) | called by mutect2, pindel, varscan2
- ELFN2 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ELK3 | c.1015T>A p.L339M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EMSY | c.600del p.K200Nfs*18 | Frame Shift Del (DEL) | VAF 17/181 reads (9%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- EPS8L2 | c.382A>G p.N128D | Missense Mutation (SNP) | VAF 47/363 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- EPX | c.1778T>C p.L593P | Missense Mutation (SNP) | VAF 67/520 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESRRB | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 99/515 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- EXO1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOSC6 | c.512A>C p.D171A | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EXOSC8 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAAP20 | c.239T>A p.V80D | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- FAM131A | c.692A>G p.D231G (on ENST00000310585; = p.D262G on NM_144635.5) | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2
- FAM135B | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FAM135B | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- FAM168A | c.366del p.Y123Tfs*89 (on ENST00000064778 / NM_001286050.2; = p.Y114Tfs*89 on NM_015159.3) | Frame Shift Del (DEL) | VAF 20/212 reads (9%) | called by mutect2, pindel
- FAM221B | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2
- FAM90A26 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, varscan2
- FARP1 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FASTKD3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- FBXL6 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXW7 | c.2001del p.S668Vfs*39 (on ENST00000281708 / NM_001349798.2; = p.S588Vfs*39 on NM_018315.5) | Frame Shift Del (DEL) | VAF 39/375 reads (10%) | called by mutect2, pindel, varscan2
- FCGBP | c.12152C>T p.A4051V | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FCGR1A | c.154A>C p.S52R | Missense Mutation (SNP) | VAF 229/1195 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FGD6 | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- FKBP10 | c.21del p.S8Afs*151 | Frame Shift Del (DEL) | VAF 31/240 reads (13%) | called by mutect2, varscan2
- FKBP4 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FKRP | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FLII | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FLNC | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 76/622 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- FLNC | c.4573C>A p.P1525T | Missense Mutation (SNP) | VAF 82/594 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLRT1 | c.397del p.H133Tfs*52 | Frame Shift Del (DEL) | VAF 24/207 reads (12%) | called by mutect2, pindel, varscan2
- FNIP2 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- FOXD4L3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 35/706 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- FOXR1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FREM2 | c.6796C>T p.P2266S | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FREM3 | c.4068G>T p.Q1356H | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FRMPD4 | c.3313dup p.S1105Kfs*31 | Frame Shift Ins (INS) | VAF 34/189 reads (18%) | called by mutect2, pindel, varscan2
- FRYL | c.4948_4950del p.L1650del | In Frame Del (DEL) | VAF 8/51 reads (16%) | called by pindel, varscan2
- FSD1L | c.640_641del p.V214Nfs*11 | Frame Shift Del (DEL) | VAF 25/190 reads (13%) | called by mutect2, pindel, varscan2
- FSIP2 | c.3664del p.T1222Hfs*9 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- FUT9 | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FXR1 | c.821dup p.A275Gfs*2 | Frame Shift Ins (INS) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- GAK | c.1813dup p.D605Gfs*18 | Frame Shift Ins (INS) | VAF 17/148 reads (11%) | called by mutect2, pindel, varscan2
- GAK | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 37/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GALNS | c.1019dup p.S341Qfs*24 | Frame Shift Ins (INS) | VAF 46/417 reads (11%) | called by mutect2, pindel, varscan2
- GALR1 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GASK1B | c.910+7G>T | Splice Region (SNP) | VAF 51/435 reads (12%) | called by muse, mutect2, varscan2
- GATD1 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.292); called by muse, mutect2
- GBA | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 91/819 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF5 | c.157del p.L53Wfs*34 | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | called by mutect2, varscan2
- GDF6 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- GFRA1 | c.792del p.F264Lfs*15 | Frame Shift Del (DEL) | VAF 37/379 reads (10%) | called by mutect2, pindel
- GLB1L2 | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.516); called by muse, mutect2
- GMNN | c.230del p.N77Ifs*13 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- GNA11 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GNAS | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 55/335 reads (16%) | called by muse, mutect2, varscan2
- GPATCH8 | c.2207del p.P736Lfs*373 | Frame Shift Del (DEL) | VAF 22/139 reads (16%) | called by mutect2, pindel, varscan2
- GPR84 | c.303del p.F101Lfs*9 | Frame Shift Del (DEL) | VAF 31/257 reads (12%) | called by mutect2, pindel, varscan2
- GPR89A | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- GRAMD1B | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 41/309 reads (13%) | called by muse, mutect2, varscan2
- GRIN2A | c.4031T>C p.F1344S | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- GRM8 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- GSC | c.734G>T p.R245M | Missense Mutation (SNP) | VAF 125/658 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- H2AC21 | c.205A>G p.N69D | Missense Mutation (SNP) | VAF 34/534 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HADH | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- HDLBP | c.3089C>A p.A1030D | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- HERPUD1 | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- HIF3A | c.1610C>A p.P537H (on ENST00000377670 / NM_152795.4; = p.P468H on NM_022462.4) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2
- HIVEP2 | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLTF | c.176del p.L59Yfs*5 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- HMCN2 | c.12500T>C p.V4167A | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNRNPU | c.1806G>T p.Q602H (on ENST00000283179; = p.Q664H on NM_004501.3) | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HNRNPUL2 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.157); called by muse, mutect2
- HPCAL1 | c.117dup p.T40Hfs*103 | Frame Shift Ins (INS) | VAF 28/263 reads (11%) | called by mutect2, pindel, varscan2
- HPSE2 | c.1560G>T p.K520N | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- HSP90AA1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR4 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.067); called by muse, mutect2
- HUNK | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICMT | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- IDH3A | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IER3 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IFRD1 | c.1113dup p.H372Tfs*4 | Frame Shift Ins (INS) | VAF 28/220 reads (13%) | called by mutect2, varscan2
- IGF2R | c.6062G>C p.G2021A | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2
- IGHV3OR16-8 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 54/606 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); called by muse, mutect2
- IGSF3 | c.3538T>C p.C1180R (on ENST00000369486 / NM_001007237.3; = p.C1200R on NM_001542.4) | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL1RL2 | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.034); called by muse, mutect2
- INPP4B | c.2315A>G p.E772G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2
- INSR | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS2 | c.3077C>A p.P1026H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- INTS4 | c.1695C>G p.F565L | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); called by muse, mutect2
- IQCA1 | c.1662G>A p.W554* | Nonsense Mutation (SNP) | VAF 47/392 reads (12%) | called by muse, mutect2, varscan2
- ITGA9 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITM2B | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); called by muse, mutect2
- JADE1 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- JARID2 | c.3216del p.E1073Kfs*106 | Frame Shift Del (DEL) | VAF 21/218 reads (10%) | called by mutect2, pindel, varscan2
- KANK4 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- KASH5 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KAT6A | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNH4 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNK12 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- KCNK4 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- KDF1 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.058); called by muse, mutect2
- KDM5A | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.195); called by muse, mutect2
- KHDRBS1 | c.161del p.G54Afs*72 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIAA1549 | c.4618A>T p.K1540* | Nonsense Mutation (SNP) | VAF 43/365 reads (12%) | called by muse, mutect2, varscan2
- KIAA1614 | c.2955del p.S986Rfs*15 | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | called by mutect2, pindel
- KIAA2012 | c.1902G>C p.E634D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.11); called by muse, varscan2
- KIF25 | c.1042G>A p.A348T (on ENST00000354419 / NM_030615.2; = p.A296T on NM_005355.3) | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.065); called by muse, mutect2
- KIF26B | c.3414del p.K1138Nfs*32 | Frame Shift Del (DEL) | VAF 25/163 reads (15%) | called by mutect2, pindel, varscan2
- KIF3B | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5C | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLC4 | c.734C>A p.S245* | Nonsense Mutation (SNP) | VAF 33/346 reads (10%) | called by muse, mutect2
- KMT2D | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- KNTC1 | c.2959_2962del p.F987Kfs*25 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- KPNA6 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.806); called by muse, mutect2
- KRT14 | c.1400dup p.L468Pfs*15 | Frame Shift Ins (INS) | VAF 26/233 reads (11%) | called by mutect2, pindel, varscan2
- KRT6A | c.395dup p.G133Wfs*30 | Frame Shift Ins (INS) | VAF 32/260 reads (12%) | called by mutect2, varscan2
- KRTAP5-5 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- LAMA5 | c.4038_4039del p.C1346* | Nonsense Mutation (DEL) | VAF 38/382 reads (10%) | called by pindel, varscan2
- LAMB3 | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- LAMC3 | c.2968G>C p.E990Q | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LFNG | c.625G>A p.A209T (on ENST00000222725 / NM_001040167.2; = p.A80T on NM_002304.2) | Missense Mutation (SNP) | VAF 54/475 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- LGALS16 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LIN54 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LIPF | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2
- LIX1L | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 53/513 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH2 | c.1025del p.N342Ifs*49 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- LRP1B | c.9898T>G p.C3300G | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRP8 | c.2552G>A p.W851* | Nonsense Mutation (SNP) | VAF 41/241 reads (17%) | called by muse, mutect2, varscan2
- LRRC9 | c.975G>C p.K325N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2
- LRRK1 | c.2807A>C p.N936T | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LTBR | c.96+2T>C p.X32_splice | Splice Site (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- LVRN | c.2852A>G p.N951S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LY6G6E | c.184del p.S62Afs*35 | Frame Shift Del (DEL) | VAF 48/524 reads (9%) | called by mutect2, pindel
- MACF1 | c.13261G>T p.G4421C (on ENST00000372915; = p.G2354C on NM_012090.5) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- MAGEC1 | c.2200del p.E734Rfs*11 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- MAGED1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
758 further variants in this file (273 protein-altering or splice-affecting, 299 silent, 186 other) are not listed here.
